Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FX-01A (Primary Tumor).

TSS Patient ID:

Case #: JOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **metaplastic carcinoma**

Date of Procurement: Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **3**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

1CD-0-3

Path - carcinoma, metaplastic, NOS 8575/3
Site: breast, NOS C50.9 w 10/21/11

CQCF - carcinoma, infiltrating ductal, NOS 8540/3

w 10/21/11

Source: NCI Genomic Data Commons file 44f219e5-900d-4dfb-aa54-967e702a9f40 (TCGA-AN-A0FX.0CC079D3-EB90-47B5-B554-599A67C9E12A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).